Surgical pathology report (de-identified scan), TCGA case TCGA-CZ-5464, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Harvard, specimen TCGA-CZ-5464-01A (Primary Tumor).

[page 1 of 2]
Pathology Report

Accession Number: [REDACTED]
Type: Surgical Pathology
Specimen Type: Kidney, partial or total resection
Procedure Date: [REDACTED]
Ordering Provider: [REDACTED]

Report Status: Final

CASE: [REDACTED]
PATIENT: [REDACTED]

CGA-CZ-5464

PATHOLOGIC DIAGNOSIS:

SPECIMEN DESIGNATED "LEFT KIDNEY WITH PIECE OF RENAL VEIN":

RENAL CELL CARCINOMA, clear cell type, Fuhrman nuclear grade II, multifocal, in kidney parenchyma (largest focus, 7.5 cm, in upper pole to middle region), extension into perirenal soft tissue and renal vein (see NOTE).

Renal artery, inked margins, and Gerota's fascia are negative for tumor.

Adrenal gland is negative for tumor.

Renal vein margin is positive for tumor.

Lymphovascular invasion is present in perirenal blood vessels.

AJCC Classification (6th Edition): T3b Nx MX.

NOTE:

Some of the separate nodules grossly appear to be due to venous spread.

CLINICAL DATA:

History: None given.

Operation: Left radical nephrectomy with IVC resection.

Operative Findings: None given.

Clinical Diagnosis: Left renal mass.

TISSUE SUBMITTED:

A/1. Left kidney with piece of renal vein (FS for tumor bank).

GROSS DESCRIPTION:

The specimen is received fresh, labeled with the patient's name, unit number, and "#1. Left kidney and piece of renal vein", and consists of a left radical nephrectomy specimen (940 grams; 21.0 x 14.0 x 9.5 cm), to include: kidney (13.0 x 8.0 x 7.5 cm), renal artery (1.9 cm in length x 0.5 cm in diameter), distorted renal vein (4.0 cm in length x 2.7 cm in diameter), ureter (3.7 cm in length x 0.5 cm in diameter), abundant perinephric adipose tissue with attached Gerota fascia (9.2 x 7.0 x 0.1 cm). The deep margin is inked black and the specimen is bivalved, exhibiting a golden yellow/red, dominantly solid, focally cystic, nodular, ill-defined mass (5.0 x 4.5 x 4.2 cm) within the upper pole, grossly invading/obstructing and dilating the renal vein, and protruding from the renal vein margin. Multiple golden yellow/red, hemorrhagic tumor nodules (ranging from 0.2 up to 1.5 cm in diameter) extend from the aforementioned upper pole mass into the mid and focally lower pole parenchyma (approximately 50% involvement). Tumor grossly involves multiple medium and small caliber vessels (subvein/venule). The upper pole mass and additional tumor nodules do not grossly invade through the renal capsule. The ureter/pelvicocaliceal system is distally edematous. The pelvicocaliceal system and renal arteries grossly uninvolved by tumor. Multiple dark brown/red nodules (? lymph node versus tumor in venule), ranging from 0.3 up to 0.6 cm in greatest dimension within the perihilar adipose tissue. The remaining parenchyma exhibits a well-defined corticomedullary junction. Also, received in the same container is a segment of grossly distorted, unoriented probable renal vein (5.2 cm in length x up to 2.6 cm in diameter) with golden yellow/red, firm tumor bulging from both resection margins. One end is marked by an undesignated suture (inked black) and the opposing end is inked blue. Sectioning exhibits tumor focally invading into the vein wall. Representative tissue is submitted to the tissue bank as follows: T1 equals upper pole mass/hemorrhagic area; T2 equals upper pole mass golden yellow area; T3 equals upper pole mass fibrous area; T4 equals

[page 2 of 2]
Accession Number: [REDACTED]

Report Status: Final

Type: Cytogenetics

CASE: [REDACTED]

PATIENT

Cy [REDACTED]

TCGA-CZ-5464

KARYOTYPE: T1: 45,X,-Y,del(3)(p173p273),t(3;15)(p173;q276)[cp4]
T3: 45,X,-Y,del(3)(p173p273) T4: 46,XY[3]

METAPHASES COUNTED: 10 ANALYZED: 10 SCORED: 0 BANDING: GTG

INTERPRETATION:

Four different specimens from this tumor were received.

All metaphases from specimens labeled T1 and T3 contained the clonal aberrations described above. Both specimens contain an identical interstitial deletion of the short arm of chromosome 3, a characteristic finding in renal cell carcinoma, clear cell type.

No metaphases were available from specimen labeled T2, therefore the cytogenetic analysis could not be performed.

No cytogenetic aberrations were identified in metaphases analyzed from specimen labeled T4. This normal result does not exclude a neoplastic proliferation.

COMMENTS:

Mosaicism and small chromosome anomalies may not be detectable using the standard methods employed. Chromosome analysis was performed at a level of 400 bands or greater.

INDICATION FOR TEST:

RCC

[REDACTED]

Source: NCI Genomic Data Commons file cf2470fb-6cf3-4c6b-8400-66409d85018a (TCGA-CZ-5464.FA6121BC-D626-46B4-B60A-B48002A27E29.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).